Somatic mutation profile of tumor specimen TCGA-AA-3833-01A (aliquot TCGA-AA-3833-01A-01W-0900-09) from TCGA case TCGA-AA-3833, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.0 years (23,011 days).
Specimen TCGA-AA-3833-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e34b67e-2fce-471d-a216-23955a002a19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3833-10A (Blood Derived Normal), aliquot TCGA-AA-3833-10A-01W-1982-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c839ecb-e74d-4a8f-b076-ad2766479aa6

The open-access MAF lists 749 somatic variants for this specimen: 570 protein-altering or splice-affecting, 166 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 395, Silent 166, Frame Shift Del 116, Nonsense Mutation 22, Frame Shift Ins 21, Splice Region 7, Splice Site 7, RNA 7, Intron 6, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs1054938291, COSV52807462; ClinVar: likely pathogenic; called by muse, mutect2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 72/348 reads (21%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2, varscan2
- FRMPD4 | c.1851del p.C618Vfs*8 | Frame Shift Del (DEL) | VAF 67/355 reads (19%) | catalogued as rs886038208; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, pindel
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 58/286 reads (20%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, varscan2
- AAK1 | c.2342C>A p.P781H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV68646309; called by muse, mutect2, varscan2
- ABCG1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1445295054, COSV59201332; called by muse, mutect2, varscan2
- ABLIM3 | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV58647806; called by muse, mutect2, varscan2
- AC244197.3 | c.72del p.K25Rfs*44 | Frame Shift Del (DEL) | VAF 34/198 reads (17%) | catalogued as CD972265, CD983359; called by pindel, varscan2
- ACKR1 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 30/543 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100929663; called by muse, mutect2
- ACP7 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs1199368105, COSV58700675; called by muse, mutect2, varscan2
- ACTA1 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64204060; called by muse, mutect2, varscan2
- ACTL7A | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV61776470; called by muse, mutect2, varscan2
- ACVR1B | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV57779712; called by muse, mutect2, varscan2
- ADAM15 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs148719743; called by muse, mutect2, varscan2
- ADAMTS10 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs782582238; called by muse, mutect2
- ADAMTS16 | c.1016T>G p.I339S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99942984; called by muse, mutect2
- ADGRA3 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 148/755 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.503); catalogued as rs754833054, COSV51560289; called by muse, mutect2, varscan2
- ADGRG7 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1289887177, COSV99841544; called by muse, mutect2
- ADGRV1 | c.12211C>T p.R4071* | Nonsense Mutation (SNP) | VAF 21/111 reads (19%) | catalogued as rs1163308590, COSV67993770; called by muse, mutect2, varscan2
- ADORA2A | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781339364, COSV58380268; called by muse, mutect2, varscan2
- AHNAK2 | c.11177T>C p.M3726T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.159); catalogued as rs1488162721, COSV60927844; called by muse, mutect2, varscan2
- AKAP4 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 123/601 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1557204114, COSV62075364; called by muse, mutect2, varscan2
- AL441992.2 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs770205049, COSV56913694; called by muse, mutect2
- ALAS2 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100238648; called by muse, mutect2
- ALDH1L2 | c.2756T>C p.V919A | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51557229; called by muse, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 38/177 reads (21%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- ANKRD11 | c.2987G>A p.G996D | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as COSV56369863; called by muse, mutect2, varscan2
- ANKRD17 | c.4933A>G p.T1645A | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV58226649; called by muse, mutect2
- ANO4 | c.583C>T p.R195C (on ENST00000392977 / NM_001286615.2; = p.R160C on NM_178826.4) | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs144445830, COSV54610059, COSV54617836; called by muse, mutect2, varscan2
- AOX1 | c.738del p.V247* | Frame Shift Del (DEL) | VAF 49/331 reads (15%) | catalogued as rs1559234318, COSV65981656; called by mutect2, pindel, varscan2
- AP1G2 | c.2263del p.L755Cfs*3 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as rs1192178097; called by mutect2, pindel, varscan2
- APAF1 | c.2510C>T p.T837M (on ENST00000551964 / NM_181861.2; = p.T826M on NM_013229.3) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.353); catalogued as rs200461221, COSV59667778; called by muse, mutect2, varscan2
- APBB3 | c.848C>T p.A283V (on ENST00000357560 / NM_133173.2; = p.A290V on NM_006051.3) | Missense Mutation (SNP) | VAF 26/327 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs141902691; called by muse, mutect2
- APCS | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV54818349; called by mutect2, varscan2
- APMAP | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54176732; called by muse, mutect2, varscan2
- APOBEC1 | c.207del p.K69Nfs*12 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | catalogued as rs753365818; called by mutect2, pindel, varscan2
- ARAP3 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.581); catalogued as COSV53354054; called by muse, mutect2, varscan2
- ARHGAP21 | c.4849del p.D1617Tfs*32 | Frame Shift Del (DEL) | VAF 47/282 reads (17%) | catalogued as COSV57604106; called by mutect2, pindel, varscan2
- ARHGAP22 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372857506; called by muse, mutect2, varscan2
- ARHGEF18 | c.568G>A p.A190T (on ENST00000359920 / NM_001130955.2; = p.A86T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1421608652, COSV100150046; called by muse, mutect2
- ARSI | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV60817083; called by muse, mutect2, varscan2
- ARSL | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1192188568, CM1513901, COSV66965510; called by muse, mutect2, varscan2
- ASH1L | c.4393A>G p.T1465A | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.038); catalogued as rs984193480, COSV100853603; called by muse, mutect2
- ASIC4 | c.1319T>C p.L440P (on ENST00000347842 / NM_182847.3; = p.L459P on NM_018674.6) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61733109; called by muse, mutect2, varscan2
- ATG16L1 | c.387A>G p.A129= | Splice Region (SNP) | VAF 30/140 reads (21%) | catalogued as COSV61467521; called by muse, mutect2, varscan2
- ATP10D | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759172595, COSV56710131; called by muse, mutect2, varscan2
- ATP8A2 | c.2852A>C p.Q951P | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54972333; called by muse, mutect2, varscan2
- ATP8B2 | c.1013G>A p.R338H (on ENST00000672630; = p.R305H on NM_001005855.2) | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs1353271203, COSV59245873; called by muse, mutect2, varscan2
- ATRNL1 | c.2478G>A p.M826I | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV58110871; called by muse, mutect2, varscan2
- B3GNT2 | c.495G>T p.W165C | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57345616; called by muse, mutect2, varscan2
- BASP1 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1478735559, COSV100493739; called by muse, mutect2
- BCKDK | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV54893612; called by muse, mutect2
- BCL9L | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747439249, COSV58319212; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 15/105 reads (14%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BICDL1 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1355968585, COSV57494374; called by muse, mutect2, varscan2
- BMPR1A | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64407490, COSV64408290; called by muse, mutect2, varscan2
- BMPR1B | c.944T>C p.L315S | Missense Mutation (SNP) | VAF 81/463 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52781148; called by muse, mutect2, varscan2
- BST2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.025); catalogued as COSV53089663; called by muse, mutect2, varscan2
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs771322722; called by mutect2, pindel
- C16orf72 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59916415; called by muse, mutect2, varscan2
- C17orf100 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs755335599; called by muse, varscan2
- C19orf53 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV55606565; called by muse, mutect2, varscan2
- C2CD5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, mutect2
- C6orf15 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV52539799; called by muse, mutect2, varscan2
- CACNG3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV50064715; called by muse, mutect2, varscan2
- CALD1 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV62652918; called by muse, mutect2, varscan2
- CAMK1G | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 66/393 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs145309971; called by muse, mutect2, varscan2
- CASP5 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775692401, COSV52831239; called by muse, mutect2, varscan2
- CATSPERD | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100486969; called by muse, mutect2, varscan2
- CBLL2 | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); catalogued as COSV100081555; called by muse, mutect2
- CCBE1 | c.955del p.E319Rfs*80 | Frame Shift Del (DEL) | VAF 23/85 reads (27%) | catalogued as rs1568138188; called by mutect2, pindel, varscan2
- CCDC57 | c.1290G>A p.W430* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV58936899; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | catalogued as rs747079826; called by mutect2, varscan2
- CCZ1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs777676532; called by mutect2, varscan2
- CDC25A | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1167314662, COSV56769565; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH23 | c.9902C>A p.P3301H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56485297; called by muse, mutect2, varscan2
- CEMIP2 | c.1991C>G p.T664S | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV100987511; called by muse, mutect2
- CEP164 | c.3871C>T p.P1291S | Missense Mutation (SNP) | VAF 87/305 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.787); catalogued as rs1454720853, COSV54045610; called by muse, mutect2, varscan2
- CEP350 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as COSV62486180; called by muse, mutect2, varscan2
- CER1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as rs748038785, COSV66603872; called by muse, mutect2
- CFAP20DC | c.1040C>T p.P347L (on ENST00000482387 / NM_001351530.2; = p.P222L on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as rs141916956, COSV55920191; called by muse, mutect2, varscan2
- CHD6 | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV58561520; called by muse, mutect2, varscan2
- CHRD | c.2466G>T p.E822D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV52611902; called by muse, mutect2, varscan2
- CHST1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768248608, COSV57324012; called by muse, mutect2, varscan2
- CHST15 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs750910183, COSV60562428; called by muse, mutect2, varscan2
- CMTM2 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as rs762401460, COSV51749551; called by muse, mutect2, varscan2
- CNNM1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV63203032; called by muse, mutect2, varscan2
- CNTLN | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs932660734, COSV52093867; called by muse, mutect2, varscan2
- CNTNAP2 | c.754+2T>A p.X252_splice | Splice Site (SNP) | VAF 25/132 reads (19%) | catalogued as COSV100672864; called by muse, mutect2, varscan2
- COBLL1 | c.2729G>A p.G910D (on ENST00000392717; = p.G872D on NM_014900.5) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV52075131; called by muse, mutect2, varscan2
- COL6A3 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV55105512; called by muse, mutect2, varscan2
- COL7A1 | c.7453C>T p.R2485C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs868422300, COSV60396155; called by muse, mutect2, varscan2
- CPEB2 | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 32/436 reads (7%) | catalogued as COSV52591959; called by muse, mutect2
- CPLANE2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.263); catalogued as rs202049255, COSV65057366; called by muse, mutect2, varscan2
- CRTAP | c.1073C>A p.A358E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58014859; called by muse, mutect2, varscan2
- CSMD1 | c.7430A>C p.N2477T (on ENST00000520002; = p.N2476T on NM_033225.6) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100153724; called by muse, mutect2, varscan2
- CSMD3 | c.11105C>T p.T3702M (on ENST00000297405 / NM_001363185.1; = p.T3533M on NM_052900.3) | Missense Mutation (SNP) | VAF 8/257 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1163363504, COSV52203591; called by muse, mutect2
- CSNK1A1L | c.690del p.K230Nfs*31 | Frame Shift Del (DEL) | VAF 43/257 reads (17%) | catalogued as rs369743261; called by mutect2, pindel, varscan2
- CTNNA1 | c.1479del p.K493Nfs*31 | Frame Shift Del (DEL) | VAF 91/543 reads (17%) | catalogued as COSV57081469; called by mutect2, pindel, varscan2
- CTNNA2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63571948; called by muse, mutect2
- CTNNAL1 | c.886A>T p.I296F | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV57705154; called by muse, mutect2, varscan2
- CTSA | c.990del p.C331Afs*36 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | catalogued as rs758642867; called by mutect2, pindel, varscan2
- CUTC | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1270066633, COSV100976185; called by muse, mutect2, varscan2
- CYP11B1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs773245244, COSV52826584, COSV99455806; called by muse, mutect2, varscan2
- CYP4Z1 | c.1509dup p.V504Sfs*10 | Frame Shift Ins (INS) | VAF 32/130 reads (25%) | catalogued as rs759035167; called by mutect2, varscan2
- DAB1 | c.210C>T p.G70= | Splice Region (SNP) | VAF 14/93 reads (15%) | catalogued as rs143307821; called by muse, mutect2, varscan2
- DCAF12L1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as COSV64422659; called by muse, mutect2, varscan2
- DCAF5 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV58462630; called by muse, mutect2, varscan2
- DCC | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1568281411, COSV59117151; called by muse, mutect2, varscan2
- DCDC1 | c.460T>C p.F154L | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV60855976; called by muse, mutect2, varscan2
- DDI2 | c.661A>T p.I221L | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.463); catalogued as COSV60781206; called by muse, mutect2, varscan2
- DHX58 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs782757668, COSV52427911; called by muse, mutect2, varscan2
- DIP2A | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as rs977935511, COSV59485634; called by muse, mutect2, varscan2
- DIS3L | c.1624G>A p.V542I (on ENST00000319212 / NM_001143688.3; = p.V459I on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as rs757341504, COSV59914031; called by muse, mutect2
- DLG2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV54678972; called by muse, mutect2
- DMD | c.9574G>T p.G3192W | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58945586; called by muse, mutect2, varscan2
- DMRTC2 | c.755+1G>A p.X252_splice | Splice Site (SNP) | VAF 16/256 reads (6%) | catalogued as COSV99523487; called by muse, mutect2
- DMXL2 | c.718T>C p.W240R | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51854405; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAJA4 | c.895G>A p.G299R (on ENST00000343789; = p.G328R on NM_018602.3) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV51216548; called by muse, mutect2, varscan2
- DNMBP | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs199965546, COSV60631769; called by muse, mutect2, varscan2
- DNMT3A | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs773312511, COSV53073643, COSV99261457; called by muse, mutect2, varscan2
- DOCK3 | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 81/423 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773719061, COSV56545609; called by muse, mutect2, varscan2
- DOCK4 | c.3931C>T p.R1311C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550574924, COSV69855426; called by muse, mutect2, varscan2
- DOP1B | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as rs575242531, COSV101215844; called by muse, mutect2, varscan2
- DPPA3 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.451); catalogued as COSV61503531; called by muse, mutect2, varscan2
- DSEL | c.2434C>T p.R812* | Nonsense Mutation (SNP) | VAF 58/310 reads (19%) | catalogued as rs1251262629, COSV59494086; called by muse, mutect2, varscan2
- DSP | c.6122G>A p.S2041N | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65795172; called by muse, mutect2, varscan2
- DTX2 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.598); catalogued as COSV56864526; called by muse, mutect2, varscan2
- DUOXA2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as rs1235332304, COSV50994509; called by muse, mutect2
- DUSP10 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as COSV60459431; called by muse, mutect2, varscan2
- DVL2 | c.1761G>T p.E587D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV50039165; called by muse, mutect2, varscan2
- DVL2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50037345; called by muse, mutect2, varscan2
- DZIP3 | c.3388G>A p.A1130T | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100848086; called by muse, mutect2
- ECPAS | c.2742G>A p.W914* | Nonsense Mutation (SNP) | VAF 34/157 reads (22%) | catalogued as COSV52195000, COSV52205896; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV62570367; called by muse, mutect2, varscan2
- EGF | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99490281; called by muse, mutect2, varscan2
- EIF3A | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 192/818 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs757558927, COSV64960821; called by muse, mutect2, varscan2
- EIF5A | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59752910; called by muse, mutect2, varscan2
- ELMOD3 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 24/221 reads (11%) | catalogued as COSV55708621; called by muse, mutect2, varscan2
- ELOA2 | c.2097C>A p.S699R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV55307125; called by muse, mutect2, varscan2
- EMC2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV55211012; called by muse, mutect2, varscan2
- ENGASE | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs550081329, COSV56138163; called by muse, mutect2
- EPHA3 | c.2222G>A p.G741D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60723535; called by muse, mutect2, varscan2
- EPHA5 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); catalogued as rs756849899, COSV56656014; called by muse, mutect2, varscan2
- ERAS | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV54433347; called by muse, mutect2, varscan2
- ERC2 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs371754235; called by muse, mutect2, varscan2
- ESYT3 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1039044847, COSV101272764; called by mutect2, varscan2
- EWSR1 | c.1713G>A p.M571I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100132095; called by muse, mutect2, varscan2
- EXOC4 | c.2028-1G>T p.X676_splice | Splice Site (SNP) | VAF 45/203 reads (22%) | catalogued as COSV99555746; called by muse, mutect2, varscan2
- F8 | c.3870del p.E1292Rfs*16 | Frame Shift Del (DEL) | VAF 105/601 reads (17%) | catalogued as rs1426645898, CD022147, CD0911173, COSV64270790; called by mutect2, pindel, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 20/159 reads (13%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM169A | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.709); catalogued as rs771668934, COSV65847164; called by muse, mutect2, varscan2
- FAM76A | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV50549800; called by muse, mutect2, varscan2
- FAM83C | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.234); catalogued as COSV65584180; called by muse, mutect2, varscan2
- FASTKD1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs774513827, COSV71624782; called by muse, mutect2, varscan2
- FAT4 | c.11207del p.L3736Yfs*8 | Frame Shift Del (DEL) | VAF 35/209 reads (17%) | catalogued as rs1314412769; called by mutect2, pindel, varscan2
- FBXL5 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV58013415; called by muse, mutect2, varscan2
- FBXO10 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99447269; called by muse, mutect2
- FCHSD1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.42); catalogued as rs749738737, COSV53354043; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 27/187 reads (14%) | catalogued as rs1288807478; called by mutect2, varscan2
- FGD5 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV53250409; called by muse, mutect2, varscan2
- FGF13 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV59549598; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FNDC1 | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); catalogued as rs781002567, COSV51935811, COSV99796097; called by mutect2, varscan2
- FOLR1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs752503322, COSV56617069; called by muse, mutect2, varscan2
- FRAS1 | c.9239G>A p.R3080H | Missense Mutation (SNP) | VAF 56/375 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224276472, COSV53641155; called by muse, mutect2, varscan2
- FRYL | c.8266T>C p.C2756R | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51959615; called by muse, mutect2, varscan2
- FSTL5 | c.844T>A p.W282R | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60223404; called by muse, mutect2, varscan2
- FYB1 | c.208_210del p.S70del | In Frame Del (DEL) | VAF 22/138 reads (16%) | catalogued as rs776134568; called by pindel, varscan2
- FYCO1 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs536061109, COSV56118913; called by muse, mutect2, varscan2
- GABBR1 | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 57/522 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs745435524, COSV63544249; called by muse, mutect2, varscan2
- GABPB2 | c.1275_1276dup p.T426Rfs*4 | Frame Shift Ins (INS) | VAF 16/98 reads (16%) | catalogued as rs780452255; called by mutect2, varscan2
- GABRQ | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.781); catalogued as rs782073807, COSV64783672; called by muse, mutect2
- GALNT14 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs1018404705, COSV61110134; called by muse, mutect2, varscan2
- GAS7 | c.977G>A p.R326H (on ENST00000432992 / NM_201433.2; = p.R186H on NM_003644.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV60442605; called by muse, mutect2
- GBA2 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as rs112979503, COSV62306693; called by muse, mutect2
- GCNA | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 160/791 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.476); catalogued as rs752166814, COSV65468034; called by muse, mutect2, varscan2
- GFRA1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV62609863; called by muse, mutect2, varscan2
- GJA1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as CM055952; called by muse, mutect2, varscan2
- GMFG | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53419742; called by muse, mutect2, varscan2
- GNB1L | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs572852392, COSV61549614; called by muse, mutect2
- GPC2 | c.1666del p.A556Hfs*31 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs753572388; called by mutect2, pindel
- GPR22 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV51756591; called by muse, mutect2, varscan2
- GPT2 | c.605del p.G202Afs*8 | Frame Shift Del (DEL) | VAF 22/154 reads (14%) | catalogued as COSV60838783; called by mutect2, pindel, varscan2
- GPX2 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as COSV100767506, COSV63036658; called by muse, mutect2
- GRID1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763688764, COSV60048994; called by muse, mutect2, varscan2
- GRIK5 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1455244911, COSV53478591; called by muse, mutect2, varscan2
- GRIN2A | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs542256226, COSV58053870; called by muse, mutect2, varscan2
- GRIN2B | c.3412C>T p.R1138* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as rs1203043074, COSV101663020, COSV74207464; called by muse, mutect2, varscan2
- HAS3 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.748); catalogued as rs774289115, COSV54708907; called by muse, mutect2, varscan2
- HDAC9 | c.122T>A p.V41D | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV67783527; called by muse, mutect2, varscan2
- HDGFL2 | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1366871532; called by muse, mutect2
- HELZ | c.4738A>T p.I1580F | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100699063; called by muse, mutect2
- HNRNPL | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV55495158; called by muse, mutect2, varscan2
- HSPB2 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); catalogued as COSV57052411; called by muse, mutect2, varscan2
- ICE1 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as rs1168165491, COSV56830994; called by muse, mutect2, varscan2
- IDH2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as rs201173543, COSV57480752; called by muse, mutect2, varscan2
- IDS | c.545T>A p.L182Q | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM981027, COSV61714118; called by muse, varscan2
- IFNLR1 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777122633, COSV59527483; called by muse, mutect2, varscan2
- IGBP1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV60557207; called by muse, mutect2, varscan2
- IGF1R | c.3008G>A p.R1003Q | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs754969104, COSV51271729; called by muse, mutect2, varscan2
- IGFBP4 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as COSV54096874; called by muse, mutect2, varscan2
- IL21R | c.1079del p.G360Afs*20 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as COSV61969550; called by mutect2, pindel, varscan2
- IMPDH2 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as rs761159150, COSV58247168; called by muse, mutect2
- INO80 | c.3896G>A p.R1299Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs778207798, COSV62742174; called by muse, mutect2, varscan2
- INTS3 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); catalogued as COSV55162702; called by muse, mutect2, varscan2
- IPO8 | c.1966C>T p.L656F | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV56243368, COSV56244960; called by muse, mutect2, varscan2
- IQGAP1 | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51590401; called by muse, mutect2, varscan2
- IQSEC1 | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56221041; called by muse, mutect2, varscan2
- ITPR1 | c.2087A>G p.E696G (on ENST00000354582; = p.E681G on NM_002222.7) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57000279; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JAKMIP2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 86/455 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs774610220, COSV54597568; called by muse, mutect2, varscan2
- KANK4 | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs1390022806, COSV58093929; called by muse, mutect2, varscan2
- KBTBD6 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV65271889; called by muse, mutect2, varscan2
- KCNA4 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.998); catalogued as rs756447343, COSV60251351; called by muse, mutect2, varscan2
- KCND1 | c.1162T>G p.F388V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV54415641; called by muse, mutect2, varscan2
- KCND3 | c.949T>C p.C317R | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56188319; called by muse, mutect2, varscan2
- KDSR | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750015953, COSV58507974; called by muse, mutect2, varscan2
- KIAA1109 | c.14227C>T p.R4743C | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767116983, COSV52662892; called by muse, mutect2, varscan2
- KIAA1217 | c.5173C>A p.L1725I | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.052); catalogued as COSV100287305; called by muse, mutect2
- KIF13B | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs766406923, COSV72954322; called by muse, mutect2, varscan2
- KIF24 | c.4064G>A p.C1355Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99903593; called by muse, mutect2, varscan2
- KIF4B | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 67/293 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs775211305, COSV70530189; called by muse, mutect2, varscan2
- KLF17 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 26/166 reads (16%) | catalogued as COSV64856952; called by muse, mutect2, varscan2
- KLHL40 | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55136859; called by muse, mutect2, varscan2
- KLHL6 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV100385053; called by muse, mutect2
- KLK4 | c.612C>T p.N204= | Splice Region (SNP) | VAF 44/229 reads (19%) | catalogued as COSV100133719; called by muse, mutect2, varscan2
- KMT2D | c.15223G>A p.G5075R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764161037, COSV56479053, COSV99040273, COSV99985342; called by muse, mutect2, varscan2
- KMT2D | c.4496G>T p.G1499V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV56479095; called by muse, mutect2, varscan2
- KRT25 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as rs776093481, COSV56446306; called by muse, mutect2, varscan2
- KRT34 | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67450550; called by muse, mutect2, varscan2
- KRT73 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV59841338; called by muse, mutect2, varscan2
- KRT79 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs921269254, COSV57940406, COSV57942467; called by muse, mutect2, varscan2
- KRTAP10-6 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV59976993; called by muse, mutect2, varscan2
- L3MBTL3 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100696409; called by muse, mutect2, varscan2
- LAMA1 | c.1414G>C p.V472L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67543324; called by muse, mutect2, varscan2
- LAMA2 | c.8853A>C p.K2951N | Missense Mutation (SNP) | VAF 39/430 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.399); catalogued as COSV70353633; called by muse, mutect2
- LAMA4 | c.829G>A p.V277I (on ENST00000230538 / NM_001105206.3; = p.V270I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146225813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB3 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868446895, COSV61919151; called by muse, mutect2, varscan2
- LAMC3 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs144206115; called by mutect2, varscan2
- LANCL1 | c.373A>G p.N125D | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs750087496, COSV52064024, COSV52066819; called by muse, mutect2, varscan2
- LENG8 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58728055; called by muse, mutect2, varscan2
- LGR5 | c.1670G>A p.G557D | Missense Mutation (SNP) | VAF 97/474 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV57009125; called by muse, mutect2, varscan2
- LILRB2 | c.565A>G p.N189D | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV58747932; called by muse, mutect2
- LINGO2 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs767025672, COSV58057613; called by muse, mutect2, varscan2
- LNPEP | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs760096595, COSV51481857; called by muse, mutect2
- LNX2 | c.1358G>T p.S453I | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV100310910; called by muse, varscan2
- LRFN3 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as rs1255358039, COSV55819044; called by muse, mutect2, varscan2
- LRFN5 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as COSV53271853; called by muse, mutect2, varscan2
- LRP2 | c.9256C>T p.R3086C | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs761770923, COSV55548238; called by muse, mutect2, varscan2
- LRRC31 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV52982452; called by muse, mutect2, varscan2
- LRRC41 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 97/576 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV58442011; called by muse, mutect2, varscan2
- LRRK1 | c.3340G>A p.G1114R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs768286875, COSV52624466, COSV99442418; called by muse, mutect2, varscan2
- LRRN3 | c.1815dup p.C606Mfs*12 | Frame Shift Ins (INS) | VAF 33/156 reads (21%) | catalogued as rs747411092; called by mutect2, varscan2
- LRRTM2 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 132/609 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs751764437, COSV51224405; called by muse, mutect2, varscan2
- LYZL2 | c.308A>G p.Y103C (on ENST00000375318; = p.Y57C on NM_183058.3) | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs752589166, COSV64684874; called by muse, mutect2, varscan2
- MAGEB4 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.666); catalogued as COSV66776458; called by muse, mutect2, varscan2
- MAGEC3 | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 56/319 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV71610184; called by muse, mutect2, varscan2
- MAGIX | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.221); catalogued as COSV66255700; called by muse, mutect2, varscan2
- MAP2K3 | c.117dup p.P40Tfs*19 (on ENST00000342679 / NM_145109.3; = p.P11Tfs*19 on NM_002756.4) | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | catalogued as rs35080482; called by mutect2, pindel, varscan2
- MAP3K19 | c.1247C>A p.A416D | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59638870, COSV59641213; called by muse, mutect2, varscan2
- MAP3K4 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747914971, COSV62335605; called by muse, mutect2, varscan2
- MARCO | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.198); catalogued as rs200590124; called by muse, mutect2, varscan2
- MARK2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 107/507 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV59286098; called by muse, mutect2, varscan2
- MBD5 | c.3014C>A p.A1005D | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.095); catalogued as COSV68698736; called by muse, mutect2, varscan2
- MBP | c.835G>A p.D279N (on ENST00000355994 / NM_001025101.2; = p.D161N on NM_002385.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1337832380, COSV62828920; called by muse, mutect2, varscan2
- MDM4 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV65796653; called by muse, mutect2, varscan2
- MERTK | c.2594G>A p.R865Q | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs546088670, COSV54933820, COSV99775262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MESD | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV55726351; called by muse, mutect2, varscan2
- MGST3 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV63321409; called by muse, mutect2
- MOB3C | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs780307724, COSV54720218; called by muse, mutect2, varscan2
- MORC3 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV68689130; called by muse, mutect2, varscan2
- MPP1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 244/1359 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs782624566, COSV65728680; called by muse, mutect2, varscan2
- MPP3 | c.1255C>T p.H419Y | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.692); catalogued as rs759815020, COSV68199081; called by muse, mutect2, varscan2
- MSI2 | c.405+2T>C p.X135_splice | Splice Site (SNP) | VAF 8/137 reads (6%) | catalogued as COSV52366459; called by muse, mutect2
- MTCL1 | c.2488C>T p.R830C (on ENST00000306329 / NM_001378206.1; = p.R470C on NM_015210.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs201898483; called by muse, mutect2, varscan2
- MTHFR | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV64879039; called by muse, mutect2, varscan2
- MTMR6 | c.1640G>A p.G547D | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs778518214, COSV67809509; called by muse, mutect2, varscan2
- MUC16 | c.37997C>A p.P12666H | Missense Mutation (SNP) | VAF 96/511 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV67488548; called by muse, mutect2, varscan2
- MUC16 | c.13353C>A p.S4451R | Missense Mutation (SNP) | VAF 97/518 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); catalogued as COSV67488552; called by muse, mutect2, varscan2
- MX2 | c.2018dup p.N673Kfs*12 | Frame Shift Ins (INS) | VAF 29/144 reads (20%) | catalogued as rs757958010; called by mutect2, varscan2
- MXRA5 | c.3494G>A p.R1165Q | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs774829303, COSV54247493, COSV99477269; called by muse, mutect2, varscan2
- MYCBPAP | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs748849452, COSV60406540; called by muse, mutect2
- MYLK2 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs200390693, COSV65659834; called by muse, mutect2, varscan2
- MYO19 | c.2432_2433del p.T811Sfs*19 (on ENST00000614623 / NM_001163735.1; = p.T611Sfs*19 on NM_025109.5) | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs866388163; called by pindel, varscan2
- MYT1 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60512108; called by muse, mutect2, varscan2
- NAALADL1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762860964, COSV60525110; called by muse, mutect2, varscan2
- NAV3 | c.731del p.K244Sfs*26 | Frame Shift Del (DEL) | VAF 46/182 reads (25%) | catalogued as rs35319232; called by mutect2, varscan2
- NDST3 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as COSV56618537; called by muse, mutect2, varscan2
- NDST4 | c.1491A>C p.K497N | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.209); catalogued as COSV52134358; called by muse, mutect2, varscan2
- NEIL1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs773400121, COSV51239479; called by muse, mutect2, varscan2
- NEIL2 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV99462494; called by muse, mutect2
- NEUROD6 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 19/389 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV99774199; called by muse, mutect2
- NIBAN2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs1439442732, COSV64825362; called by muse, mutect2
- NID1 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs761790846, COSV51627471; called by muse, mutect2, varscan2
- NKD1 | c.862del p.R288Afs*59 | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | catalogued as rs772439983; called by mutect2, pindel, varscan2
- NLRC5 | c.2641C>T p.Q881* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as rs955333920, COSV99348250; called by muse, mutect2, varscan2
- NLRP1 | c.3638C>T p.S1213F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769160254, COSV52576431, COSV52578528; called by muse, mutect2
- NLRP11 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs375545663; called by muse, mutect2, varscan2
- NRXN1 | c.3005C>T p.T1002I | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.399); catalogued as rs1195389843, COSV100456866; ClinVar: uncertain significance; called by muse, mutect2
- NSUN2 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs376441708; called by muse, mutect2, varscan2
- NUP133 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416012526, COSV54574741; called by muse, mutect2, varscan2
- NYAP2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56014060; called by muse, mutect2, varscan2
- OR10A3 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 89/487 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs751919581, COSV62459338, COSV62460262; called by muse, mutect2, varscan2
- OR10S1 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV73342904, COSV73343010; called by muse, mutect2, varscan2
- OR1K1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs774930032, COSV52957222; called by muse, mutect2, varscan2
- OR4K13 | c.901del p.R301Dfs*71 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs749899868, COSV100237879; called by mutect2, varscan2
- OR52N2 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs748265734, COSV57677692; called by muse, mutect2, varscan2
- OTP | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as rs867548437, COSV60568883; called by muse, mutect2, varscan2
- OTUD6B | c.783del p.K261Nfs*3 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs762934606; called by mutect2, varscan2
- PCDH17 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); catalogued as rs1447100045, COSV100932043; called by muse, mutect2
- PCDHA10 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs969097575, COSV56539188; called by muse, mutect2, varscan2
- PCDHA11 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV56490219; called by muse, mutect2, varscan2
- PCDHA12 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV56539211; called by muse, mutect2
- PCDHAC1 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs782548172, COSV53863949; called by muse, mutect2, varscan2
- PCDHB5 | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 111/558 reads (20%) | catalogued as rs201677139, COSV50647416; called by muse, mutect2, varscan2
- PCDHGA5 | c.1210C>A p.L404I | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV53909405, COSV99546947; called by muse, mutect2
- PCF11 | c.4484G>A p.S1495N | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.357); catalogued as COSV53536952; called by muse, mutect2, varscan2
- PCNX2 | c.1856del p.K619Rfs*52 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as COSV50784264; called by mutect2, pindel, varscan2
- PCYOX1L | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.24); catalogued as rs569066814, COSV51007220; called by muse, mutect2
- PELI1 | c.859A>G p.N287D | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs768293813, COSV62730768; called by muse, mutect2, varscan2
- PELP1 | c.2216T>C p.I739T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV52591545; called by muse, mutect2, varscan2
- PELP1 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as rs371213384; called by muse, mutect2, varscan2
- PGM5 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); catalogued as rs782232692, COSV67167563; called by muse, mutect2, varscan2
- PHF7 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs372765636; called by muse, mutect2, varscan2
- PHLDB2 | c.2451del p.V822Lfs*6 (on ENST00000393925 / NM_001134439.2; = p.V779Lfs*6 on NM_145753.2) | Frame Shift Del (DEL) | VAF 11/120 reads (9%) | catalogued as rs1193567996, COSV101208463; called by mutect2, pindel, varscan2
- PIK3CG | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs150482982, COSV63249405; called by muse, mutect2, varscan2
- PIK3R1 | c.997T>A p.W333R (on ENST00000521381 / NM_181523.3; = p.W63R on NM_181504.4) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57130843, COSV57137513; called by muse, mutect2, varscan2
- PIKFYVE | c.4339del p.M1447Wfs*31 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | catalogued as rs1376050974, COSV52250187; called by mutect2, pindel, varscan2
- PKHD1 | c.5707G>A p.V1903I | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs753639079, COSV61884120, COSV61891662; called by muse, mutect2, varscan2
- PLCB4 | c.2718A>T p.E906D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53815083; called by muse, mutect2, varscan2
- PLEKHH1 | c.734A>G p.H245R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV61287208; called by muse, mutect2, varscan2
- PLPP4 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs770040474, COSV64829434; called by muse, mutect2, varscan2
- PNOC | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs764588634, COSV100108409; called by muse, varscan2
- POLE | c.3479G>A p.R1160H | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757902862, COSV57688771; called by muse, mutect2, varscan2
- POLR2M | c.758+2T>C p.X253_splice | Splice Site (SNP) | VAF 6/91 reads (7%) | catalogued as COSV55211678; called by muse, mutect2
- POTEF | c.3017A>G p.Y1006C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100665347; called by mutect2, varscan2
- PPHLN1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs144485658; called by muse, mutect2, varscan2
- PPL | c.2867C>T p.T956M | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs769995678, COSV52172233; called by muse, mutect2, varscan2
- PPP1R3F | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.84); catalogued as rs782351810; called by muse, mutect2, varscan2
- PRPF40B | c.99del p.M34Cfs*29 (on ENST00000380281; = p.M28Cfs*29 on NM_012272.3) | Frame Shift Del (DEL) | VAF 46/304 reads (15%) | catalogued as COSV56058435; called by mutect2, pindel, varscan2
- PRPS1L1 | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 68/346 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV72649993; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1175C>A p.P392Q (on ENST00000352766; = p.P313Q on NM_181334.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.916); catalogued as COSV61236303; called by muse, mutect2, varscan2
- PRRG3 | c.494del p.G165Afs*7 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | catalogued as COSV64850606; called by pindel, varscan2
- PRSS12 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1454952808, COSV56609388; called by muse, mutect2, varscan2
- PSG2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 103/527 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs777210176, COSV61545245; called by muse, mutect2, varscan2
- PTPRN | c.2028del p.S677Pfs*18 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | catalogued as COSV99833836; called by mutect2, pindel, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- PUM3 | c.463dup p.R155Kfs*7 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | catalogued as rs554604549; called by mutect2, pindel, varscan2
- RALGAPA2 | c.2754del p.S919Afs*24 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as COSV99173620; called by mutect2, pindel, varscan2
- RALGPS1 | c.1446C>T p.H482= | Splice Region (SNP) | VAF 8/45 reads (18%) | catalogued as rs149497407; called by muse, mutect2, varscan2
- RAPGEF2 | c.4435G>A p.A1479T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs767807700, COSV52431564; called by muse, mutect2, varscan2
- RASEF | c.1885T>G p.F629V | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64588408; called by muse, mutect2, varscan2
- RASEF | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1306147264, COSV64588412; called by muse, mutect2, varscan2
- REC8 | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV61018082; called by muse, mutect2
- RETREG2 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs199754357, COSV56087576; called by muse, mutect2, varscan2
- REV1 | c.3166G>T p.V1056L | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as COSV51489488; called by muse, mutect2, varscan2
- REXO5 | c.194A>C p.Q65P | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV54474342; called by muse, mutect2, varscan2
- RHCG | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV51518135; called by muse, mutect2, varscan2
- RIMBP2 | c.3107C>T p.T1036M | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs762319163, COSV55482486; called by muse, mutect2, varscan2
- RIPOR1 | c.1811G>A p.S604N (on ENST00000379312 / NM_001193522.2; = p.S600N on NM_024519.4) | Missense Mutation (SNP) | VAF 226/1104 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as COSV50254233; called by muse, mutect2, varscan2
- RIPOR1 | c.3045G>A p.V1015= (on ENST00000379312 / NM_001193522.2; = p.V1011= on NM_024519.4) | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as rs201739741, COSV99243655; called by muse, varscan2
- RNF121 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1239160549, COSV62315940, COSV62317708; called by muse, mutect2, varscan2
- RNF213 | c.9343G>A p.A3115T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs746145556, COSV60391566; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RO60 | c.1295A>G p.Q432R | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV66474766; called by muse, varscan2
- ROBO1 | c.4473del p.K1491Nfs*16 | Frame Shift Del (DEL) | VAF 30/261 reads (11%) | catalogued as COSV71397837; called by mutect2, pindel, varscan2
- ROBO2 | c.2204-1G>A p.X735_splice | Splice Site (SNP) | VAF 23/118 reads (19%) | catalogued as COSV59911826, COSV59912207, COSV59934101; called by muse, mutect2, varscan2
- RP1L1 | c.6830C>A p.P2277H | Missense Mutation (SNP) | VAF 161/652 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); catalogued as COSV66759344; called by muse, mutect2, varscan2
- RP9 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 40/197 reads (20%) | catalogued as COSV51806198; called by muse, mutect2, varscan2
- RPS6KA6 | c.1739T>A p.L580* | Nonsense Mutation (SNP) | VAF 25/125 reads (20%) | catalogued as COSV53125717; called by muse, mutect2, varscan2
- RRP9 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV51756125; called by muse, mutect2, varscan2
- RYR3 | c.5171C>A p.P1724H | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66805872; called by muse, mutect2, varscan2
- SAFB | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52653552; called by muse, mutect2, varscan2
- SALL2 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as COSV58105492; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | catalogued as rs768388757; called by mutect2, pindel
- SEC61A1 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV54578652; called by muse, mutect2
- SECISBP2L | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55937265; called by muse, mutect2, varscan2
- SERPINI1 | c.242T>A p.L81Q | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.992); catalogued as COSV55514274; called by muse, mutect2, varscan2
- SESN2 | c.722del p.P241Qfs*6 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs770146088, COSV53426876; called by mutect2, varscan2
- SETD3 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs771711935, COSV59283870; called by muse, mutect2, varscan2
- SF3B3 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs1267673684, COSV56790119; called by muse, mutect2, varscan2
- SFSWAP | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs755872590, COSV99906413; called by muse, mutect2, varscan2
- SHKBP1 | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52543059; called by muse, mutect2, varscan2
- SIGLEC8 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV58475501; called by muse, mutect2, varscan2
- SIPA1L1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 18/322 reads (6%) | catalogued as COSV100666069; called by muse, mutect2
- SLC10A2 | c.152G>A p.C51Y | Missense Mutation (SNP) | VAF 21/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55361278; called by muse, mutect2
- SLC11A1 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51919002; called by muse, mutect2, varscan2
- SLC1A1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 19/299 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV99261594; called by muse, mutect2
- SLC22A4 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs200543879, COSV52358018; called by muse, mutect2, varscan2
- SLC27A1 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs759824579, COSV53097021; called by muse, mutect2, varscan2
- SLC35E4 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs372345536; called by muse, mutect2, varscan2
- SLC35F5 | c.741_742del p.F247Lfs*24 | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC41A2 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99316935; called by muse, mutect2
- SLC4A1 | c.1212G>T p.Q404H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV52262625; called by mutect2, varscan2
- SLC8B1 | c.527-3del | Splice Region (DEL) | VAF 60/269 reads (22%) | catalogued as rs771550605; called by mutect2, pindel, varscan2
- SMARCE1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs1172017371, COSV52861729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC1B | c.572del p.N191Ifs*2 | Frame Shift Del (DEL) | VAF 54/260 reads (21%) | catalogued as rs748761052; called by mutect2, varscan2
- SMYD5 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs376603112; called by muse, mutect2
- SNX27 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV64327339; called by muse, mutect2, varscan2
- SOCS6 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs374835963; called by muse, mutect2, varscan2
- SPHKAP | c.4153T>A p.S1385T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.104); catalogued as COSV60891733; called by muse, mutect2, varscan2
- SPIN2B | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 139/539 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1355565257, COSV99328212; called by muse, varscan2
- SPRY3 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 75/443 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs754497360, COSV57142077; called by muse, mutect2, varscan2
- SRPK1 | c.1912C>G p.P638A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749597130, COSV60414493, COSV60415555; called by muse, mutect2, varscan2
- STAT1 | c.2111C>A p.T704N | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV100738858; called by muse, mutect2
- STK32B | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs773060917, COSV51508331; called by muse, mutect2, varscan2
- STYXL2 | c.3184T>C p.W1062R | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV54809265; called by muse, mutect2, varscan2
- SUPT6H | c.3712G>A p.G1238S | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773794817, COSV58930891; called by muse, mutect2, varscan2
- SYNE1 | c.22045-2del p.X7349_splice (on ENST00000367255 / NM_182961.4; = p.X7278_splice on NM_033071.3) | Splice Site (DEL) | VAF 100/474 reads (21%) | catalogued as rs35128811, COSV55089044; ClinVar: uncertain significance; called by mutect2, varscan2
- SYNE1 | c.18288C>A p.D6096E (on ENST00000367255 / NM_182961.4; = p.D6025E on NM_033071.3) | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV55079434; called by muse, mutect2, varscan2
- TANK | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs916438010, COSV52047395; called by muse, mutect2, varscan2
- TAPT1 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58824325; called by muse, mutect2, varscan2
- TBC1D25 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs781829758, COSV65124007; called by muse, mutect2, varscan2
- TBCCD1 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100112149; called by muse, mutect2
- TENM2 | c.1916A>G p.Q639R (on ENST00000518659 / NM_001122679.2; = p.Q407R on NM_001080428.3) | Missense Mutation (SNP) | VAF 53/377 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV101318019, COSV69139280; called by muse, mutect2, varscan2
- TEX14 | c.2048A>C p.E683A (on ENST00000240361 / NM_001201457.2; = p.E677A on NM_031272.5) | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV53624746; called by muse, mutect2, varscan2
- TEX9 | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV61876846, COSV61880268; called by muse, mutect2
- TFAM | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs758607553, COSV65876646; called by muse, varscan2
- TGOLN2 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV56407431; called by muse, mutect2, varscan2
- THEMIS | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as rs370574765, COSV64070352; called by muse, mutect2, varscan2
- THNSL1 | c.1199G>T p.R400M | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV64479823; called by muse, mutect2, varscan2
- TIMM50 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs199511949, COSV58680517; called by muse, mutect2, varscan2
- TLE3 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs370686397; called by muse, mutect2, varscan2
- TLR10 | c.1409A>G p.E470G | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV58301993; called by muse, mutect2, varscan2
- TMEM150A | c.493G>T p.G165W (on ENST00000334462 / NM_001031738.3; = p.G112W on NM_153342.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as COSV100110609; called by muse, mutect2, varscan2
- TMEM25 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57097751; called by muse, mutect2
- TMEM260 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.346); catalogued as rs747716407, COSV55099125, COSV55099356; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 34/171 reads (20%) | catalogued as rs749773249; called by mutect2, varscan2
- TMPRSS11F | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as rs750121063, COSV62465801; called by muse, mutect2, varscan2
- TMPRSS3 | c.7del p.E3Kfs*22 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | catalogued as rs1568894367; called by mutect2, pindel, varscan2
- TMTC1 | c.596C>T p.T199M (on ENST00000539277 / NM_001193451.2; = p.T91M on NM_175861.3) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778313192, COSV55491880; called by muse, mutect2, varscan2
- TNFSF10 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as COSV53844345; called by muse, mutect2, varscan2
- TNNI3K | c.2474G>A p.C825Y | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV58564126; called by muse, mutect2, varscan2
- TPP1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs368914445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM24 | c.2531G>A p.C844Y (on ENST00000343526 / NM_015905.3; = p.C810Y on NM_003852.4) | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV58977206; called by muse, mutect2
- TRIM28 | c.2111G>A p.C704Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53401610; called by muse, mutect2, varscan2
- TRPM8 | c.2239G>A p.A747T | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs200649506; called by muse, varscan2
- TTC14 | c.170A>T p.K57M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV56013896; called by muse, mutect2, varscan2
- TTF1 | c.821del p.K274Sfs*149 | Frame Shift Del (DEL) | VAF 60/361 reads (17%) | catalogued as rs770528448; called by mutect2, varscan2
- TTN | c.26726G>T p.C8909F (on ENST00000591111; = p.C7982F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/194 reads (15%) | PolyPhen probably damaging (0.997); catalogued as COSV60293478; called by muse, mutect2, varscan2
- TTN | c.15265G>A p.A5089T (on ENST00000591111; = p.A4162T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | PolyPhen benign (0.058); catalogued as rs750622079, COSV100630094; called by muse, mutect2
- TUBGCP2 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773972291, COSV53308290; called by muse, mutect2
- TULP4 | c.3685C>T p.P1229S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.435); catalogued as COSV65579939; called by muse, mutect2, varscan2
- TWF2 | c.282C>A p.P94= | Splice Region (SNP) | VAF 8/23 reads (35%) | catalogued as rs370584351, COSV59727400; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- ULK2 | c.2417T>C p.I806T | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV64447958; called by muse, mutect2, varscan2
- ULK2 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 82/391 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64447962; called by muse, mutect2, varscan2
- UNC80 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99780983; called by muse, mutect2
- USP20 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.221); catalogued as rs200755344; called by muse, mutect2, varscan2
- USP34 | c.9046G>T p.D3016Y | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101277037; called by muse, mutect2
- UXS1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765724929, COSV51678239; called by muse, mutect2, varscan2
- VPS11 | c.814A>C p.I272L (on ENST00000620429; = p.I816L on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV99598194; called by muse, mutect2
- VPS33A | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.204); catalogued as rs200715881, COSV57358622; called by muse, mutect2
- VSX1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV65022007; called by muse, mutect2, varscan2
- VWA3A | c.2863G>A p.V955I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200655453; called by mutect2, varscan2
- WDR11 | c.3203A>G p.Q1068R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54787374; called by muse, mutect2, varscan2
- WDR47 | c.2291G>A p.W764* (on ENST00000369962 / NM_001142551.2; = p.W765* on NM_014969.5) | Nonsense Mutation (SNP) | VAF 75/394 reads (19%) | catalogued as COSV63059494; called by muse, mutect2, varscan2
- WDR59 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs545945156, COSV100049729; called by muse, mutect2
- WNK2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99944667; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- WWC3 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as COSV66506630; called by muse, mutect2
- XIRP1 | c.2327G>A p.R776Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs144904530; called by muse, mutect2, varscan2
- XIRP2 | c.9403C>G p.Q3135E (on ENST00000628543; = p.Q3310E on NM_152381.6) | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs751195997, COSV54687952; called by muse, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YTHDC1 | c.1594G>A p.V532M (on ENST00000344157 / NM_001031732.4; = p.V514M on NM_133370.4) | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV60011802; called by muse, mutect2, varscan2
- ZBTB40 | c.3001G>A p.V1001I | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as rs201903976, COSV100989106; called by muse, mutect2, varscan2
- ZC4H2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62005830; called by muse, varscan2
- ZFP3 | c.1304A>G p.E435G | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV59583872; called by muse, mutect2, varscan2
- ZFR | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV99416541; called by muse, mutect2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs751589999; called by mutect2, varscan2
- ZNF226 | c.2281G>A p.G761S | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as rs768164684, COSV56197767; called by muse, mutect2, varscan2
- ZNF227 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1347579443, COSV57313486; called by muse, mutect2, varscan2
- ZNF283 | c.988del p.W330Gfs*10 | Frame Shift Del (DEL) | VAF 46/182 reads (25%) | catalogued as rs779648677; called by mutect2, varscan2
- ZNF337 | c.1145A>C p.K382T | Missense Mutation (SNP) | VAF 65/351 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV53322877; called by muse, mutect2, varscan2
- ZNF345 | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59325062; called by muse, mutect2, varscan2
- ZNF408 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV61239119; called by muse, mutect2, varscan2
- ZNF410 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV57912041; called by muse, mutect2, varscan2
- ZNF44 | c.1586G>A p.C529Y (on ENST00000356109 / NM_001164276.2; = p.C481Y on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100633687; called by muse, mutect2, varscan2
- ZNF517 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs780431587, COSV63465267; called by muse, varscan2
- ZNF555 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.153); catalogued as rs763224777, COSV62073867; called by muse, mutect2, varscan2
- ZNF570 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV57580544; called by muse, mutect2, varscan2
- ZNF619 | c.1617del p.Q540Rfs*35 | Frame Shift Del (DEL) | VAF 72/363 reads (20%) | catalogued as rs1372461671; called by mutect2, pindel, varscan2
- ZUP1 | c.1474A>G p.S492G | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63946979; called by muse, mutect2
- ADAM7 | c.1781del p.L594Yfs*29 | Frame Shift Del (DEL) | VAF 23/122 reads (19%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.17212del p.T5738Pfs*48 | Frame Shift Del (DEL) | VAF 27/231 reads (12%) | called by mutect2, pindel, varscan2
- AMER1 | c.519del p.F173Lfs*36 | Frame Shift Del (DEL) | VAF 49/234 reads (21%) | called by mutect2, pindel, varscan2
- APOB | c.6222del p.F2074Lfs*16 | Frame Shift Del (DEL) | VAF 53/290 reads (18%) | called by mutect2, pindel, varscan2
- ARMC2 | c.1184del p.L395Yfs*7 | Frame Shift Del (DEL) | VAF 27/119 reads (23%) | called by pindel, varscan2
- ATAD2B | c.1699_1700del p.E567Ifs*7 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by pindel, varscan2
- BAZ1A | c.4364del p.L1455* | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- C1R | c.689del p.P230Lfs*100 (on ENST00000536053 / NM_001354346.2; = p.P216Lfs*100 on NM_001733.7) | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- C2CD3 | c.52del p.R18Efs*3 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- CAPN9 | c.227dup p.N76Kfs*13 | Frame Shift Ins (INS) | VAF 17/102 reads (17%) | called by mutect2, pindel, varscan2
- CDK14 | c.681del p.L228Cfs*6 (on ENST00000380050 / NM_001287135.2; = p.L210Cfs*6 on NM_012395.3) | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- CDK17 | c.206dup p.L70Ifs*30 | Frame Shift Ins (INS) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- CNIH1 | c.394del p.Y132Tfs*6 | Frame Shift Del (DEL) | VAF 13/128 reads (10%) | called by mutect2, pindel
- COBLL1 | c.846del p.Q283Nfs*18 (on ENST00000392717; = p.Q245Nfs*18 on NM_014900.5) | Frame Shift Del (DEL) | VAF 23/149 reads (15%) | called by mutect2, pindel, varscan2
- CR1 | c.4748del p.P1583Lfs*44 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- DACH2 | c.1486_1487dup p.I497Kfs*24 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- DDHD2 | c.654del p.F218Lfs*2 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- DLGAP3 | c.89G>T p.R30M | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2
- DNAH10 | c.4260dup p.E1421* (on ENST00000409039; = p.E1360* on NM_207437.3) | Frame Shift Ins (INS) | VAF 28/170 reads (16%) | called by pindel, varscan2
- DNAH3 | c.860_861del p.Y287Lfs*3 | Frame Shift Del (DEL) | VAF 55/328 reads (17%) | called by mutect2, pindel, varscan2
- DSCAML1 | c.2333del p.P778Hfs*36 (on ENST00000321322; = p.P718Hfs*36 on NM_020693.4) | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- EPHX2 | c.548del p.L183Wfs*8 | Frame Shift Del (DEL) | VAF 49/174 reads (28%) | called by mutect2, pindel, varscan2
- EXOC6 | c.1993C>T p.H665Y | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- FAT3 | c.3588dup p.A1197Cfs*51 | Frame Shift Ins (INS) | VAF 16/80 reads (20%) | called by mutect2, varscan2
- FMO1 | c.117del p.L40Cfs*62 | Frame Shift Del (DEL) | VAF 25/150 reads (17%) | called by mutect2, pindel, varscan2
- FMOD | c.799del p.A267Rfs*14 | Frame Shift Del (DEL) | VAF 47/195 reads (24%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.1161_1162dup p.D388Vfs*15 | Frame Shift Ins (INS) | VAF 28/146 reads (19%) | called by mutect2, varscan2
- IGF2R | c.6487del p.D2163Tfs*2 | Frame Shift Del (DEL) | VAF 25/149 reads (17%) | called by mutect2, pindel, varscan2
- IGFBP3 | c.502del p.L168Sfs*5 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel, varscan2
- IGHV1-46 | c.179del p.P60Lfs*10 | Frame Shift Del (DEL) | VAF 52/368 reads (14%) | called by mutect2, pindel, varscan2
- IGSF9B | c.439del p.Q147Sfs*13 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- IRX3 | c.706del p.E236Rfs*24 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- KAT8 | c.966del p.Y323Tfs*48 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | called by mutect2, pindel, varscan2
- KCNB2 | c.435dup p.E146Rfs*23 | Frame Shift Ins (INS) | VAF 88/560 reads (16%) | called by mutect2, varscan2
- KCTD20 | c.947del p.N316Tfs*64 | Frame Shift Del (DEL) | VAF 44/160 reads (28%) | called by pindel, varscan2
- KCTD3 | c.133dup p.S45Ffs*14 | Frame Shift Ins (INS) | VAF 22/118 reads (19%) | called by mutect2, varscan2
- KIAA1755 | c.1593del p.S532Afs*3 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- KMT2C | c.3741del p.K1247Nfs*56 | Frame Shift Del (DEL) | VAF 61/302 reads (20%) | called by mutect2, pindel, varscan2
- KMT5B | c.1188dup p.S397Ifs*9 | Frame Shift Ins (INS) | VAF 22/137 reads (16%) | called by mutect2, pindel, varscan2
- LCMT2 | c.1356del p.F452Lfs*11 | Frame Shift Del (DEL) | VAF 14/109 reads (13%) | called by mutect2, pindel
- LINGO2 | c.1692del p.F564Lfs*32 | Frame Shift Del (DEL) | VAF 21/196 reads (11%) | called by mutect2, varscan2
- LUC7L3 | c.582del p.C195Vfs*5 | Frame Shift Del (DEL) | VAF 34/202 reads (17%) | called by mutect2, pindel, varscan2
- LYST | c.4324_4325del p.S1442Ffs*38 | Frame Shift Del (DEL) | VAF 38/200 reads (19%) | called by pindel, varscan2
- MDGA2 | c.3036del p.I1014Lfs*8 (on ENST00000399232 / NM_001113498.2; = p.I716Lfs*8 on NM_182830.4) | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- MVK | c.417del p.A141Rfs*18 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/277 reads (14%) | called by mutect2, pindel, varscan2
- NKTR | c.1287del p.K429Nfs*37 | Frame Shift Del (DEL) | VAF 43/230 reads (19%) | called by mutect2, pindel, varscan2
- NRBP1 | c.591del p.I198Sfs*6 | Frame Shift Del (DEL) | VAF 25/135 reads (19%) | called by mutect2, pindel, varscan2
- OR1D5 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.436); called by muse, mutect2
- OR52K1 | c.44dup p.L15Ffs*40 | Frame Shift Ins (INS) | VAF 82/497 reads (16%) | called by mutect2, pindel, varscan2
- PAX5 | c.295dup p.I99Nfs*3 | Frame Shift Ins (INS) | VAF 58/353 reads (16%) | called by mutect2, pindel, varscan2
- PAXBP1 | c.2499dup p.K834Qfs*32 | Frame Shift Ins (INS) | VAF 25/175 reads (14%) | called by mutect2, pindel, varscan2
- PHF3 | c.2626del p.I876Yfs*26 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- PIK3R3 | c.883del p.M295* | Frame Shift Del (DEL) | VAF 44/250 reads (18%) | called by mutect2, varscan2
- PPM1H | c.678del p.T227Hfs*30 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- PRDM4 | c.1579dup p.Y527Lfs*3 | Frame Shift Ins (INS) | VAF 28/151 reads (19%) | called by mutect2, pindel, varscan2
- PRDM5 | c.775del p.D259Mfs*15 | Frame Shift Del (DEL) | VAF 19/125 reads (15%) | called by mutect2, pindel, varscan2
- PSMG2 | c.782del p.P261Lfs*36 | Frame Shift Del (DEL) | VAF 24/148 reads (16%) | called by mutect2, pindel, varscan2
- PTDSS2 | c.687_688dup p.S230Tfs*34 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- QTRT2 | c.824del p.F275Sfs*5 | Frame Shift Del (DEL) | VAF 73/362 reads (20%) | called by mutect2, pindel, varscan2
- RAD51AP2 | c.946del p.T316Lfs*2 | Frame Shift Del (DEL) | VAF 19/117 reads (16%) | called by mutect2, pindel, varscan2
- RBM27 | c.2447_2448del p.K816Tfs*63 | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | called by mutect2, varscan2
- RNF133 | c.833del p.F278Sfs*43 | Frame Shift Del (DEL) | VAF 33/212 reads (16%) | called by mutect2, pindel, varscan2
- RNF220 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 36/674 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- SCAF11 | c.1097dup p.Q367Afs*32 | Frame Shift Ins (INS) | VAF 50/284 reads (18%) | called by mutect2, pindel, varscan2
- SLC35F5 | c.1390del p.S464Hfs*5 | Frame Shift Del (DEL) | VAF 26/127 reads (20%) | called by mutect2, pindel, varscan2
- STS | c.635del p.F212Sfs*6 | Frame Shift Del (DEL) | VAF 51/287 reads (18%) | called by mutect2, pindel, varscan2
- SUPT16H | c.914del p.L305Cfs*9 | Frame Shift Del (DEL) | VAF 28/164 reads (17%) | called by mutect2, pindel, varscan2
- TARS3 | c.1271del p.F424Sfs*67 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel, varscan2
- TCF20 | c.364del p.Q122Rfs*62 | Frame Shift Del (DEL) | VAF 58/301 reads (19%) | called by mutect2, pindel, varscan2
- TCOF1 | c.1303del p.Q435Rfs*58 (on ENST00000377797 / NM_001135243.1; = p.Q358Rfs*58 on NM_000356.4) | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- TET3 | c.2290del p.A764Lfs*2 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- TEX15 | c.5122del p.R1708Gfs*3 (on ENST00000256246; = p.R2091Gfs*3 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 18/153 reads (12%) | called by mutect2, pindel, varscan2
- THSD7A | c.3026del p.N1009Mfs*47 | Frame Shift Del (DEL) | VAF 54/549 reads (10%) | called by mutect2, pindel, varscan2
- TM9SF2 | c.154_155del p.K52Efs*16 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- TNKS | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSHZ3 | c.1464del p.D489Tfs*19 | Frame Shift Del (DEL) | VAF 102/438 reads (23%) | called by mutect2, varscan2
- WHRN | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZAN | c.8083del p.E2695Rfs*83 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, pindel, varscan2
- ZKSCAN2 | c.1776del p.S593Afs*37 | Frame Shift Del (DEL) | VAF 32/195 reads (16%) | called by mutect2, pindel, varscan2
- ZNF292 | c.452del p.L151* | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel
- ZNF516 | c.2529del p.M844Cfs*131 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- ACRV1 | c.501G>A p.E167= | Silent (SNP) | VAF 63/294 reads (21%) | catalogued as COSV59755320; called by muse, varscan2
- ACSBG1 | c.2097G>A p.T699= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs375772785, COSV51909931; called by muse, mutect2, varscan2
- ACSM1 | c.534G>A p.Q178= | Silent (SNP) | VAF 60/303 reads (20%) | catalogued as COSV54639367; called by muse, mutect2, varscan2
- ACSS3 | c.1809A>G p.V603= | Silent (SNP) | VAF 41/259 reads (16%) | catalogued as rs778735071, COSV54099718; called by muse, mutect2, varscan2
- ACTR1B | c.555T>C p.I185= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV56705484; called by muse, mutect2, varscan2
- ADAMTS16 | c.2328C>T p.I776= | Silent (SNP) | VAF 56/430 reads (13%) | catalogued as COSV99942985; called by muse, mutect2, varscan2
- ADAMTS16 | c.3333G>A p.P1111= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs766617039, COSV56993076; called by muse, mutect2, varscan2
- ADCY2 | c.231G>A p.A77= | Silent (SNP) | VAF 53/249 reads (21%) | catalogued as rs748528690, COSV57895256; called by muse, mutect2, varscan2
- AEBP1 | c.2061G>A p.A687= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs558299236, COSV56256728; called by muse, mutect2, varscan2
- AFP | c.1494C>T p.G498= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV56926757; called by muse, mutect2, varscan2
- AMER1 | c.1938G>A p.R646= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as COSV57666355; called by muse, mutect2, varscan2
- ANK2 | c.5005C>T p.L1669= | Silent (SNP) | VAF 95/438 reads (22%) | catalogued as COSV52162389, COSV52183833; called by muse, mutect2, varscan2
- ANKRD11 | c.4536C>T p.R1512= | Silent (SNP) | VAF 6/153 reads (4%) | catalogued as COSV56361954; called by muse, mutect2
- ANKRD45 | c.426G>A p.R142= | Silent (SNP) | VAF 38/224 reads (17%) | catalogued as COSV60962368; called by muse, mutect2, varscan2
- ANO2 | c.1287C>T p.S429= (on ENST00000356134 / NM_001278597.3; = p.S433= on NM_001278596.3) | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV100502311; called by muse, mutect2, varscan2
- ARHGAP32 | c.6180C>A p.T2060= (on ENST00000310343 / NM_001378025.1; = p.T1711= on NM_014715.4) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV59854559; called by muse, mutect2, varscan2
- ATF2 | c.1398C>A p.T466= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as COSV51373755; called by muse, mutect2, varscan2
- ATG4A | c.450A>G p.T150= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV58967237; called by muse, mutect2, varscan2
- BMP1 | c.204A>G p.V68= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs749485360, COSV59244694; called by muse, mutect2, varscan2
- C14orf28 | c.771A>G p.T257= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as rs1455612493, COSV57334111; called by muse, mutect2, varscan2
- CADM1 | c.613C>T p.L205= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as COSV100523389; called by muse, mutect2, varscan2
- CADM4 | c.450C>A p.S150= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV55929762; called by muse, mutect2, varscan2
- CALHM4 | c.906T>C p.N302= (on ENST00000368596 / NM_001366078.1; = p.N116= on NM_153036.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1427041684, COSV100888906; called by muse, mutect2
- CAMKV | c.1143C>T p.P381= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs947599904, COSV56557458, COSV99615692; called by muse, mutect2, varscan2
- CCDC137 | c.558G>A p.R186= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV61303851; called by muse, mutect2, varscan2
- CCDC27 | c.1398G>A p.T466= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs746902221, COSV53902757; called by muse, mutect2, varscan2
- CDC45 | c.564C>T p.Y188= | Silent (SNP) | VAF 36/202 reads (18%) | catalogued as rs367976893; called by muse, mutect2, varscan2
- CDK11B | c.1785C>A p.T595= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV58340956; called by muse, mutect2, varscan2
- CDK5R1 | c.237G>A p.T79= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV55577552, COSV55578629; called by muse, mutect2, varscan2
- CEP104 | c.534C>T p.S178= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs201775417, COSV65511923; called by muse, mutect2
- CNDP2 | c.291C>T p.Y97= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs376422174; called by muse, mutect2, varscan2
- CNOT6 | c.612G>A p.R204= | Silent (SNP) | VAF 28/178 reads (16%) | catalogued as COSV56163813; called by muse, mutect2, varscan2
- COL1A1 | c.2361C>T p.S787= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs781457915, COSV56806624; called by muse, mutect2, varscan2
- CRACD | c.1986G>A p.A662= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs777771925, COSV51729966; called by muse, mutect2, varscan2
- CRYZ | c.147C>T p.P49= | Silent (SNP) | VAF 58/279 reads (21%) | catalogued as rs777169233, COSV61718504; called by muse, mutect2, varscan2
- CSMD1 | c.8604C>T p.N2868= (on ENST00000520002; = p.N2867= on NM_033225.6) | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs368720706; called by muse, mutect2, varscan2
- CSRNP3 | c.204T>C p.S68= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV58784627; called by muse, mutect2, varscan2
- CSTF2 | c.207A>G p.T69= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs778016639, COSV63376495; called by muse, mutect2, varscan2
- CTBP2 | c.942G>A p.P314= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs74769610, COSV58337451; called by muse, mutect2, varscan2
- CUL9 | c.685C>T p.L229= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as rs753030432, COSV52733638; called by muse, mutect2, varscan2
- CYP11A1 | c.1401C>T p.I467= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as rs781028010, COSV51434461; called by muse, mutect2, varscan2
- CYP3A5 | c.1434G>A p.T478= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs745883666, COSV56122722; called by muse, mutect2, varscan2
- CYP4B1 | c.1038C>T p.R346= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as rs762334759, COSV54723544; called by muse, mutect2, varscan2
- DAAM2 | c.1371G>A p.E457= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99227079; called by muse, mutect2, varscan2
- DLGAP2 | c.939C>T p.S313= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs759413221, COSV70097828; called by muse, mutect2, varscan2
- DNAH10 | c.5382C>T p.N1794= (on ENST00000409039; = p.N1733= on NM_207437.3) | Silent (SNP) | VAF 43/235 reads (18%) | catalogued as rs767366047, COSV69000002; called by muse, mutect2, varscan2
- DNAH17 | c.1416C>T p.A472= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs140578969; called by muse, mutect2, varscan2
- DNAJC13 | c.1554T>C p.H518= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV53456694; called by muse, mutect2, varscan2
- DNAJC2 | c.39C>T p.T13= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs745467570, COSV50793751; called by muse, mutect2, varscan2
- DNMT3A | c.1179T>C p.S393= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV53061667; called by muse, mutect2, varscan2
- DOCK3 | c.4239C>T p.C1413= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs781050493, COSV56523838; called by muse, mutect2, varscan2
- DYRK2 | c.1155G>A p.S385= (on ENST00000344096 / NM_006482.3; = p.S312= on NM_003583.4) | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as rs146652644; called by muse, mutect2, varscan2
- EID2 | c.393C>T p.N131= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs1326460783, COSV101180509; called by muse, mutect2
- EIF2D | c.888C>T p.H296= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV55115262; called by muse, mutect2, varscan2
- ELP2 | c.1092G>A p.A364= | Silent (SNP) | VAF 45/435 reads (10%) | catalogued as rs367642754; called by muse, mutect2, varscan2
- EMC4 | c.486G>A p.S162= | Silent (SNP) | VAF 35/235 reads (15%) | catalogued as rs375492262; called by muse, mutect2, varscan2
- FANCF | c.399G>T p.L133= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV59417004; called by muse, mutect2, varscan2
- FGD1 | c.1614C>G p.S538= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV100911255; called by muse, mutect2, varscan2
- FLVCR1 | c.1435T>C p.L479= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV65324325; called by muse, mutect2, varscan2
- FOLR2 | c.648C>T p.N216= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs755949946, COSV53352322; called by muse, mutect2, varscan2
- FREM2 | c.6420C>T p.S2140= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as rs144582052; called by muse, mutect2
- GARRE1 | c.633C>T p.G211= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as rs373171001; called by muse, mutect2
- GLRB | c.189A>G p.L63= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV52421517; called by muse, mutect2, varscan2
- GPATCH4 | c.477G>A p.G159= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs8937, COSV58041325; called by muse, mutect2, varscan2
- GPLD1 | c.2139C>T p.R713= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as rs369479070; called by muse, mutect2, varscan2
- GPR15 | c.1038T>C p.H346= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs1267034613, COSV99423953; called by muse, mutect2
- GPR156 | c.897T>C p.C299= | Silent (SNP) | VAF 29/179 reads (16%) | catalogued as COSV59942110; called by muse, mutect2, varscan2
- GRHL3 | c.1299C>T p.C433= (on ENST00000350501 / NM_198174.3; = p.C438= on NM_021180.3) | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs1339620350, COSV99359695; called by muse, mutect2, varscan2
- GRIPAP1 | c.1662C>T p.H554= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as rs369687653, COSV64553223; called by muse, mutect2, varscan2
- GRM7 | c.414C>T p.N138= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs909354514, COSV63128922; called by muse, mutect2, varscan2
- GRN | c.414G>A p.T138= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs543344476, COSV50006953; called by muse, mutect2, varscan2
- GSAP | c.2190T>G p.A730= | Silent (SNP) | VAF 11/216 reads (5%) | catalogued as COSV99990514; called by muse, mutect2
- GTF2H2C | c.387G>A p.T129= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs750631889, COSV66287272; called by mutect2, varscan2
- GYS2 | c.450T>C p.N150= | Silent (SNP) | VAF 81/433 reads (19%) | catalogued as rs1238469960, COSV53927768; called by muse, mutect2, varscan2
- H4C5 | c.225G>A p.E75= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as rs1401737332, COSV63486902; called by muse, mutect2, varscan2
- HADH | c.795C>T p.V265= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as rs143416676; ClinVar: likely benign; called by muse, mutect2, varscan2
- HAPLN1 | c.939C>T p.S313= | Silent (SNP) | VAF 39/179 reads (22%) | catalogued as rs749934033, COSV57147848; called by muse, mutect2, varscan2
- HJURP | c.1146G>A p.S382= | Silent (SNP) | VAF 14/193 reads (7%) | catalogued as rs201340488, COSV100982603; called by muse, mutect2
- HLA-E | c.1056G>T p.G352= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs575525017, COSV64927879; called by muse, mutect2, varscan2
- HMCN1 | c.14478C>T p.C4826= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs764373225, COSV54934123; called by muse, mutect2, varscan2
- HOXA1 | c.537C>A p.S179= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as COSV99761340, COSV99761409; called by muse, mutect2
- HOXA2 | c.714C>T p.S238= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as COSV56067575; called by muse, mutect2, varscan2
- HOXA3 | c.555G>A p.P185= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV57828517; called by muse, mutect2, varscan2
- IBSP | c.801C>A p.G267= | Silent (SNP) | VAF 41/236 reads (17%) | catalogued as COSV56897081; called by muse, mutect2, varscan2
- INHBA | c.753C>T p.G251= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs776081862, COSV54224528; called by muse, mutect2, varscan2
- IP6K1 | c.690G>A p.R230= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV57696482; called by muse, mutect2, varscan2
- IRS1 | c.3051A>G p.T1017= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV59338464; called by muse, mutect2
- IRX3 | c.1422C>G p.L474= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV61668739; called by muse, mutect2
- KBTBD12 | c.948C>T p.Y316= | Silent (SNP) | VAF 70/347 reads (20%) | catalogued as rs762009825, COSV59678205; called by muse, mutect2, varscan2
- KCNB1 | c.2271C>T p.D757= | Silent (SNP) | VAF 41/177 reads (23%) | catalogued as rs190726852, COSV65570487; called by muse, mutect2, varscan2
- KCND3 | c.654C>T p.C218= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1375898037, COSV56185872; called by muse, mutect2, varscan2
- KCNH8 | c.1707C>T p.T569= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV100111041, COSV60477394; called by muse, mutect2
- KDM5C | c.1065G>A p.L355= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100949463; called by muse, mutect2, varscan2
- KRT75 | c.1527G>T p.G509= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV52874985; called by muse, mutect2, varscan2
- LRFN5 | c.54G>A p.Q18= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV53271845; called by muse, mutect2, varscan2
- LRP6 | c.3891T>C p.S1297= | Silent (SNP) | VAF 57/272 reads (21%) | catalogued as COSV53792996; called by muse, mutect2, varscan2
- LRRC32 | c.930C>T p.S310= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs749913376, COSV52635112; called by muse, mutect2, varscan2
- LY9 | c.666C>T p.C222= | Silent (SNP) | VAF 51/419 reads (12%) | catalogued as COSV54437179; called by muse, mutect2, varscan2
- MAGEB1 | c.54G>A p.A18= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1234340016, COSV66776465; called by muse, mutect2, varscan2
- MAP1B | c.858C>T p.G286= | Silent (SNP) | VAF 76/444 reads (17%) | catalogued as rs777817448, COSV57099167; called by muse, varscan2
- MARK1 | c.390G>A p.K130= | Silent (SNP) | VAF 49/281 reads (17%) | catalogued as COSV65070761; called by muse, mutect2, varscan2
- MASP1 | c.63C>T p.T21= | Silent (SNP) | VAF 43/242 reads (18%) | catalogued as rs779419283, COSV51463324, COSV99397385; called by muse, mutect2, varscan2
- METTL5 | c.255C>T p.D85= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs554782778, COSV53625841; called by muse, mutect2, varscan2
- MICAL3 | c.1335C>T p.Y445= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99262904; called by muse, mutect2
- MYF6 | c.120C>A p.T40= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV57353038; called by muse, mutect2, varscan2
- NAV1 | c.5253C>T p.G1751= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV55224623; called by muse, mutect2, varscan2
- NCOA1 | c.2754T>C p.C918= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as COSV56051672; called by muse, mutect2, varscan2
- NCOA7 | c.1770G>A p.P590= | Silent (SNP) | VAF 37/227 reads (16%) | catalogued as rs369216530; called by muse, mutect2, varscan2
- NFATC4 | c.655C>A p.R219= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV51610049; called by muse, mutect2, varscan2
- NOB1 | c.864T>C p.C288= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs536540729, COSV52062916; called by muse, mutect2, varscan2
- NPBWR1 | c.108G>T p.L36= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- NRK | c.300C>T p.Y100= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV54604936; called by muse, mutect2, varscan2
- NUMBL | c.339C>T p.S113= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs376443919; called by muse, mutect2, varscan2
- OLFM1 | c.1059G>A p.S353= (on ENST00000371793 / NM_001282611.2; = p.S335= on NM_014279.5) | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs757534525, COSV53281781; called by muse, mutect2, varscan2
- OR10H2 | c.123C>T p.G41= | Silent (SNP) | VAF 106/522 reads (20%) | catalogued as rs769488901, COSV59946874; called by muse, mutect2, varscan2
- OR52L1 | c.639T>C p.N213= | Silent (SNP) | VAF 67/372 reads (18%) | catalogued as rs767368620, COSV59988833; called by muse, mutect2, varscan2
- OR5D16 | c.402C>T p.Y134= | Silent (SNP) | VAF 87/522 reads (17%) | catalogued as COSV65722767; called by muse, mutect2, varscan2
- OTX1 | c.969C>T p.G323= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs765513748, COSV56995923; called by muse, mutect2, varscan2
- PARP4 | c.2706G>A p.A902= | Silent (SNP) | VAF 68/389 reads (17%) | catalogued as rs201350007, COSV67961034; called by muse, mutect2
- PCDHA5 | c.1278G>A p.A426= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV65352344; called by muse, mutect2, varscan2
- PCDHGA5 | c.2334G>A p.T778= | Silent (SNP) | VAF 8/139 reads (6%) | catalogued as rs1477897734, COSV54016470, COSV54017936; called by muse, mutect2
- PDE4D | c.1818C>T p.S606= (on ENST00000340635 / NM_001104631.2; = p.S470= on NM_006203.4) | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs368591431, COSV100401734, COSV57720223; called by muse, mutect2, varscan2
- PDSS1 | c.801C>T p.T267= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as rs759224454, COSV66060055; called by muse, mutect2, varscan2
- PELI2 | c.567C>T p.G189= | Silent (SNP) | VAF 54/330 reads (16%) | catalogued as rs1375192647, COSV50712109; called by muse, mutect2, varscan2
- PLD5 | c.369A>G p.S123= (on ENST00000442594; = p.S61= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV59164492; called by muse, mutect2, varscan2
- POLG | c.3003C>T p.G1001= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs146064249; called by muse, mutect2, varscan2
- PPFIA3 | c.2151C>A p.P717= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV61954316; called by muse, mutect2, varscan2
- PPIAL4G | c.219C>T p.T73= | Silent (SNP) | VAF 55/485 reads (11%) | catalogued as rs367921294, COSV70087259; called by muse, mutect2, varscan2
- PPM1A | c.1113C>T p.D371= | Silent (SNP) | VAF 11/149 reads (7%) | catalogued as rs369842708; called by muse, mutect2
- PRKDC | c.1713C>T p.S571= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs373088662, COSV100043159; called by muse, mutect2, varscan2
- PTH2R | c.1083G>T p.L361= | Silent (SNP) | VAF 19/189 reads (10%) | catalogued as COSV55919702; called by muse, mutect2, varscan2
- PTK2 | c.2472C>T p.R824= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as COSV61791025; called by muse, mutect2, varscan2
- RBM28 | c.1251G>A p.A417= | Silent (SNP) | VAF 160/815 reads (20%) | catalogued as rs754195447, COSV56164545; ClinVar: likely benign; called by muse, mutect2, varscan2
- RELN | c.7854T>C p.S2618= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs746109326, COSV59029566; called by muse, mutect2, varscan2
- RHBDL2 | c.531T>C p.F177= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs770198871, COSV56709666; called by muse, mutect2, varscan2
- ROBO1 | c.4185C>A p.G1395= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV71397838; called by muse, mutect2, varscan2
- RSPH1 | c.336C>A p.T112= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV52320877; called by muse, mutect2, varscan2
- SAFB | c.1716G>A p.V572= | Silent (SNP) | VAF 24/322 reads (7%) | catalogued as COSV99413185; called by muse, mutect2
- SCAF8 | c.2784G>A p.P928= | Silent (SNP) | VAF 115/582 reads (20%) | catalogued as rs755760383, COSV65793532; called by muse, mutect2, varscan2
- SCTR | c.873C>T p.N291= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs140060251; called by mutect2, varscan2
- SNX5 | c.939C>T p.T313= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs373050708; called by muse, mutect2, varscan2
- SPNS1 | c.1254C>T p.A418= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs779495290, COSV57956504; called by muse, mutect2, varscan2
- SUN2 | c.636G>A p.T212= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs200221237, COSV53306619; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNGR2 | c.105C>T p.F35= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs762011021, COSV56746514; called by muse, mutect2
- TAF1C | c.360G>A p.A120= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs756147045, COSV58988882; called by muse, mutect2, varscan2
- TENM4 | c.5097C>T p.S1699= | Silent (SNP) | VAF 91/396 reads (23%) | catalogued as COSV53663204; called by muse, mutect2, varscan2
- TENT5A | c.1287G>A p.T429= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as rs760896955, COSV60787382; called by muse, mutect2, varscan2
- THADA | c.5589A>G p.P1863= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV56699878; called by muse, mutect2, varscan2
- TIAM1 | c.1221G>A p.A407= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV54566440, COSV99739748; called by muse, mutect2
- TICAM1 | c.399G>T p.L133= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV50239031; called by muse, mutect2
- TNN | c.2658C>T p.D886= | Silent (SNP) | VAF 133/721 reads (18%) | catalogued as rs187781360; called by muse, mutect2, varscan2
- TP63 | c.1950C>A p.I650= | Silent (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- TRIO | c.4281G>A p.Q1427= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as rs1301534093, COSV100710959; called by muse, mutect2
- TRPC4 | c.1935T>C p.S645= | Silent (SNP) | VAF 22/227 reads (10%) | catalogued as COSV59014632; called by muse, mutect2, varscan2
- TSHZ3 | c.2298G>A p.P766= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs368908849, COSV53672099; called by muse, mutect2, varscan2
- TSKU | c.915G>A p.L305= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV60752743; called by muse, varscan2
- TTC1 | c.102T>C p.P34= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV51466528; called by muse, mutect2, varscan2
- WNK3 | c.1434A>G p.K478= | Silent (SNP) | VAF 55/244 reads (23%) | catalogued as COSV63615602; called by muse, mutect2, varscan2
- ZBED4 | c.735C>T p.C245= | Silent (SNP) | VAF 39/174 reads (22%) | catalogued as rs752539183, COSV53464352; called by muse, mutect2, varscan2
- ZBTB14 | c.958C>T p.L320= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV63697274; called by muse, mutect2, varscan2
- ZFHX4 | c.7110G>T p.T2370= | Silent (SNP) | VAF 46/347 reads (13%) | catalogued as rs374869797, COSV50534522, COSV99254900; called by muse, mutect2, varscan2
- ZNF365 | c.696G>A p.L232= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs747964663, COSV101237994; called by muse, varscan2
- ZNF491 | c.285G>A p.R95= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as rs1484556475, COSV60056655; called by muse, mutect2, varscan2
- ZNF595 | c.858T>C p.C286= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as COSV59550007; called by muse, mutect2
- ZNF668 | c.1095C>T p.R365= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV56218420; called by muse, mutect2, varscan2
- ZNF81 | c.1626T>C p.N542= | Silent (SNP) | VAF 7/218 reads (3%) | catalogued as COSV100096224; called by muse, mutect2
- BX119917.1 | n.76G>A | RNA (SNP) | VAF 18/154 reads (12%) | catalogued as rs201809828; called by muse, mutect2, varscan2
- CLCN5 | c.17-33807G>A | Intron (SNP) | VAF 115/382 reads (30%) | catalogued as rs377356657, COSV101067211, COSV101067328; called by muse, mutect2, varscan2
- DCHS2 | n.1305C>T | RNA (SNP) | VAF 7/36 reads (19%) | catalogued as rs1384923227, COSV59737760; called by muse, mutect2, varscan2
- ERCC6 | c.1397+6922C>T | Intron (SNP) | VAF 29/235 reads (12%) | catalogued as rs1466603009, COSV100876212; called by muse, varscan2
- KNOP1P1 | n.74del | RNA (DEL) | VAF 20/128 reads (16%) | catalogued as rs746412924; called by mutect2, pindel, varscan2
- MAGED1 | c.46-340C>T | Intron (SNP) | VAF 14/71 reads (20%) | catalogued as COSV58516587; called by muse, mutect2, varscan2
- MIR16-1 | n.6C>T | RNA (SNP) | VAF 35/149 reads (23%) | called by muse, mutect2, varscan2
- MIRLET7C | n.6C>T | RNA (SNP) | VAF 20/87 reads (23%) | catalogued as rs374349423; called by muse, mutect2, varscan2
- OSGIN1 | n.951C>A | RNA (SNP) | VAF 5/10 reads (50%) | catalogued as COSV59676835; called by muse, mutect2, varscan2
- POLR2F | c.453-15197C>T | Intron (SNP) | VAF 37/170 reads (22%) | catalogued as rs1376331006; called by muse, mutect2, varscan2
- SLCO1A2 | c.61-458G>A | Intron (SNP) | VAF 62/310 reads (20%) | catalogued as rs775329720, COSV100262693; called by muse, mutect2, varscan2
- SSX6P | n.103C>T | RNA (SNP) | VAF 120/594 reads (20%) | catalogued as rs782319466; called by muse, mutect2, varscan2
- TTN | c.10303+2716T>C | Intron (SNP) | VAF 25/152 reads (16%) | catalogued as rs138485458, COSV100630095; called by muse, mutect2, varscan2
